MMRF case MMRF_1865 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b31085ed-f1be-46bd-859f-9812ffce570d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.0 years (20,454 days); ISS stage: I; Days to last known disease status: 1,035 days (2.8 years); Days to last follow up: 1,035 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 118 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 324 days; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 325 days; Days to treatment end: 328 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 327 days; Days to treatment end: 327 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 329 days; Days to treatment end: 329 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 2.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 338 mg/dL; Immunoglobulin G 27.6 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.69 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.55 mmol/L; Albumin 47 g/L; Total Protein 8.6 g/dL; Glucose 4.51 mmol/L.
- Day 103 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 141 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 4.35 mmol/L.
- Day 172 (ECOG 1): M Protein 1.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 202 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 14 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.93 mmol/L.
- Day 286 (ECOG 1): Hemoglobin 7.56 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 128 ×10⁹/L.
- Day 377 (ECOG 1): Lactate Dehydrogenase 8.8 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.53 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 4.84 mmol/L.
- Day 454 (ECOG 1): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.651 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.41 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.23 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 547 (ECOG 1): Lactate Dehydrogenase 11 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.73 mmol/L.
- Day 646 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 6.08 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 10.8 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 5.67 mmol/L.
- Day 747 (ECOG 2): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 1.81 g/L; Lactate Dehydrogenase 4.78 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 839 (ECOG 2): M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 2.59 g/L; Beta 2 Microglobulin 3.26 µg/mL; Lactate Dehydrogenase 10 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 6.11 mmol/L.
- Day 932 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.86 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 3.87 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 10 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.06 mmol/L.
- Day 1,035 (ECOG 2): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.74 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 3.1 g/L; Lactate Dehydrogenase 9.4 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 9.9 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.53 mmol/L; Albumin 49 g/L; Total Protein 7.8 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day 0: Weight: 52 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1865_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1865_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
